CCDI case PBBLKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d40139ff-2074-42c0-b46d-0f3bb785ef8e

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,824 days).

Biospecimens (3 samples)
- Sample 0DDC9H: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDC9I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDC9J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
